Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02J, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02J-01A (Primary Tumor).

Internal Sample I/

Diagnosis:

This is a metastasis of a poorly differentiated adenocarcinoma in the region of the liver in I),
in II) an invasive adenocarcinoma of the colon, moderately differentiated, with infiltration of all parietal layers and vascular infiltration (pT3, L1, V1), as well as free resection margins and free lymph nodes (pN0)

Comment:

In the preparation of further sections, two liver metastases were discernible.
These lay very close together.

Tumor formula:

ICDO-DA M-8140/3

G2

pT3, L1, V1, pN0 (0 of 13), pM1 (hepar)

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: sigmoid colon pN0 c40F 3/28/11
L1B-7

HIFAA Discrepancy		☒
Primary Malignancy History		☒
Reviewed Initials	km	Stu

Source: NCI Genomic Data Commons file e42fbd21-0871-40d2-b991-7df44da2b4e6 (TCGA-AA-A02J.18C139E3-62C0-4D98-8D1B-BA412EE9BE1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).